Somatic mutation profile of tumor specimen TCGA-DW-7839-01A (aliquot TCGA-DW-7839-01A-11D-2136-08) from TCGA case TCGA-DW-7839, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 58.4 years (21,347 days).
Specimen TCGA-DW-7839-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3e75394-2015-412e-8a0f-b69871b82843.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DW-7839-10A (Blood Derived Normal), aliquot TCGA-DW-7839-10A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfe0f548-acb9-469b-aef1-dc33f335674e

The open-access MAF lists 46 somatic variants for this specimen: 40 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Frame Shift Del 5, Silent 5, Nonsense Mutation 2, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2264T>C p.L755S | Missense Mutation (SNP) | VAF 40/64 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913470, COSV54062780, COSV54064269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAD2 | c.776T>A p.L259Q (on ENST00000315906 / NM_001145400.2; = p.L341Q on NM_139174.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51894466; called by muse, mutect2, varscan2
- ARF3 | c.205G>C p.G69R | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56741636; called by muse, mutect2, varscan2
- ATF3 | c.262A>G p.R88G | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58378406; called by muse, mutect2, varscan2
- B4GAT1 | c.726A>T p.E242D | Missense Mutation (SNP) | VAF 75/154 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV60820455; called by muse, mutect2, varscan2
- BOD1L1 | c.4163G>A p.S1388N | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV50033084; called by muse, mutect2, varscan2
- C1orf35 | c.4T>G p.F2V | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV54343251; called by muse, mutect2, varscan2
- CR1L | c.14T>G p.V5G | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.238); catalogued as COSV100888489, COSV65473969; called by muse, mutect2, varscan2
- CUBN | c.8080A>G p.I2694V | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.036); catalogued as COSV64722524; called by muse, mutect2, varscan2
- CYP2A6 | c.666G>A p.M222I | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs747803234, COSV56536350; called by muse, mutect2, varscan2
- CYP2A7 | c.666G>A p.M222I | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.227); catalogued as COSV52504145; called by muse, mutect2, varscan2
- DENND4C | c.1689A>T p.Q563H | Missense Mutation (SNP) | VAF 89/200 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV66822888; called by muse, mutect2, varscan2
- DMPK | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52180572; called by muse, mutect2, varscan2
- EPS8L2 | c.1397C>A p.S466* | Nonsense Mutation (SNP) | VAF 53/120 reads (44%) | catalogued as COSV59349213; called by muse, mutect2, varscan2
- FAT3 | c.11378C>T p.P3793L | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.352); catalogued as rs368909373; called by muse, mutect2, varscan2
- GRIA1 | c.1347C>G p.H449Q | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as COSV53615213; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.715G>A p.G239R (on ENST00000354667 / NM_031243.3; = p.G227R on NM_002137.4) | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.376); catalogued as COSV61160441; called by muse, mutect2, varscan2
- MBD6 | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.155); catalogued as rs755713754, COSV63075874; called by muse, mutect2, varscan2
- MED13L | c.3089C>G p.A1030G | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.628); catalogued as COSV56125782; called by muse, mutect2, varscan2
- NLRP2 | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.693); catalogued as rs774890248, COSV54758246; called by muse, mutect2, varscan2
- NRG3 | c.674C>A p.P225H | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV64575505; called by muse, mutect2, varscan2
- NUDT10 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV62854145; called by muse, mutect2, varscan2
- NUDT11 | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV65665312; called by muse, mutect2, varscan2
- PICALM | c.748T>C p.F250L | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV62672269; called by muse, mutect2, varscan2
- SLBP | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV59184151; called by muse, mutect2, varscan2
- SLC38A6 | c.175A>C p.M59L | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV50784277; called by muse, mutect2, varscan2
- SNX5 | c.393G>C p.E131D | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.674); catalogued as COSV66698317; called by muse, mutect2, varscan2
- SPAG16 | c.195C>G p.D65E | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV55988210; called by muse, mutect2, varscan2
- SREBF1 | c.1178A>G p.K393R | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV55418458; called by muse, mutect2, varscan2
- STARD13 | c.2034A>C p.Q678H (on ENST00000336934 / NM_001243476.3; = p.Q560H on NM_052851.3) | Missense Mutation (SNP) | VAF 87/177 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV55234503; called by muse, mutect2, varscan2
- TAS2R41 | c.512A>T p.K171M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.067); catalogued as COSV68765634; called by muse, mutect2, varscan2
- TNRC6A | c.2563del p.D855Ifs*48 | Frame Shift Del (DEL) | VAF 25/70 reads (36%) | catalogued as COSV59370993; called by mutect2, pindel, varscan2
- TRIM51 | c.1025A>G p.Y342C | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55269118, COSV99792579; called by muse, mutect2
- XRN1 | c.824T>A p.I275N | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV53815537; called by muse, mutect2, varscan2
- ATP11B | c.2375_2398del p.C792_K800delins* | Nonsense Mutation (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel
- COL11A1 | c.3482del p.P1161Lfs*37 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- HOMER2 | c.912dup p.V305Sfs*9 (on ENST00000304231 / NM_199330.3; = p.V294Sfs*9 on NM_004839.4) | Frame Shift Ins (INS) | VAF 45/113 reads (40%) | called by mutect2, pindel, varscan2
- LRRC14 | c.1444_1445del p.I482Lfs*15 | Frame Shift Del (DEL) | VAF 21/49 reads (43%) | called by mutect2, pindel, varscan2
- SAMD9 | c.417del p.V140Lfs*4 | Frame Shift Del (DEL) | VAF 43/116 reads (37%) | called by mutect2, pindel, varscan2
- WFDC10A | c.82del p.R28Gfs*49 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- ALMS1 | c.11799T>C p.R3933= | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as COSV52516559; called by muse, mutect2, varscan2
- ERBB2 | c.2263T>C p.L755= | Silent (SNP) | VAF 43/67 reads (64%) | catalogued as COSV54062219, COSV54066696; called by muse, mutect2, varscan2
- MGAM | c.1524T>G p.V508= | Silent (SNP) | VAF 66/137 reads (48%) | catalogued as rs1259548903, COSV72075203; called by muse, mutect2, varscan2
- PPFIBP1 | c.175T>C p.L59= | Silent (SNP) | VAF 44/95 reads (46%) | catalogued as COSV57296101; called by muse, mutect2, varscan2
- PTK7 | c.45T>G p.P15= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as COSV99432269; called by muse, mutect2, varscan2
- ANKRD54 | c.-60A>C | 5'UTR (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99316527; called by muse, mutect2, varscan2
